Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6B, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6B-01A (Primary Tumor).

[page 1 of 2]
Collect date:

ICD O.3
Adenocarcinoma, intestinal
Type 8144/3
Site: Gastroesophageal junction
C16.0
9/23/2014

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

1 -) Para-aortic lymph nodes:

- Adipose tissue without atypia.
- Absence of lymph nodes in the examined material.

2 -) Lymph nodes from level 2:

Metastatic adenocarcinoma (1/1).

3 -) Lymph nodes from chain 12:

- Adipose tissue without atypia.
- Absence of lymph nodes in the examined material.

4 -) Lymph nodes from chain 12D.

- Adipose tissue without atypia .
- Absence of lymph nodes in the examined material.

5 -) Lymph nnodes from chain 11P.

- 3 lymph nodes free of neoplasia (0/3).

6 -) Lymph nodes from chain 11L.

- Absence of neoplasia (0/1).

7 -) Lymph nodes from chain 10.

- Free of neoplasia (0/2).

8-) Esophageal margin.

- Free of neoplasia.

9 -) Stomach + distal esophagus + omentum + lymphadenectomy:

- Moderately differentiated adenocarcinoma (intestinal type of Lauren) from gastroesophageal junction, measuring 9.2 x 5.2 x 1.2 cm in its greates axes.
- The tumor compromises distal esophagus, cardia and gastric corpus, being most of it in stomach.
- Tumor infiltrates up to perigastric fat and muscular layer of esophagus.
- Presence of angiolymphatic and perineural invasions.

[page 2 of 2]
- Non-tumoral gastric mucosa exhibiting moderate chronic gastritis with discrete activity with lymphoid follicles.
- Presence of intestinal metaplasia in gastric mucosa.
- Omentum free of neoplasia.
- The research for *H. pylori* was positive.
- Absence of neoplasia in all 16 lymph nodes dissected from greater curvature (0/16).
- Metastatic adenocarcinoma in 4 of 16 lymph nodes dissected from lesser curvature, with capsular transposition (4/16).
- Surgical margins free of neoplasia.

10 -) Gallbladder.

- Chronic cholecystitis.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Gastric corpus	Adenocarcinoma, NOS	pT3 pN2

Criteria	lw 12/23/13	Yes	No

Source: NCI Genomic Data Commons file 3c5ed597-a94d-47c3-ba36-bfd25d3bde91 (TCGA-VQ-AA6B.BAD31992-32F1-4061-97DB-10CFE1A8DBD9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).